Gene-level copy-number profile of tumor specimen TCGA-D8-A1JD-01A from TCGA case TCGA-D8-A1JD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.5 years (15,166 days).
Specimen TCGA-D8-A1JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.907cd6bb-05fd-4557-b21d-d8d8d16fb8a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e408b5c9-e311-4779-a721-b92f2ece5613

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 413; copy number 2: 5,301; copy number 3: 9,314; copy number 4: 22,544; copy number 5: 3,844; copy number 6: 8,179; copy number 7: 7,556; copy number 8: 871; copy number 9: 82; copy number 10: 374; copy number 13: 191; copy number 14: 631; copy number 19: 435; copy number 21: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JD-01A-11D-A13J-01): tumor purity 0.5, ploidy 4.4, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,750 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:185,157,080–185,291,781, 1 gene, copy number 10 (within-gene range 7–10): SWT1.
- chr1:185,226,808–188,156,180, 42 genes, copy number 10: RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156.
- chr1:192,875,686–208,244,384, 331 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr8:56,252,960–145,066,685, 1,376 genes, copy number 9–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
